Somatic mutation profile of tumor specimen 0DRZJ0 from CCDI case PBCHKE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.6 years (4,592 days).
Specimen 0DRZJ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10006a42-2fff-4f98-8615-299bb7147be0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51368f41-6ac6-4eca-8d66-b8aadb17942c

The open-access MAF lists 30 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 7, Silent 6, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 304/600 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BOLL | c.266T>A p.I89N | Missense Mutation (SNP) | VAF 147/391 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99987490; called by muse, mutect2, varscan2
- CDKN2C | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 277/652 reads (42%) | catalogued as COSV52955155, COSV52955731; called by muse, mutect2, varscan2
- GALNT15 | c.1735G>T p.G579C | Missense Mutation (SNP) | VAF 270/612 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs770615479; called by muse, mutect2, varscan2
- LOXHD1 | c.4567G>A p.V1523I | Missense Mutation (SNP) | VAF 268/607 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.115); catalogued as rs547086707, COSV56065763; called by muse, mutect2, varscan2
- MCPH1 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 289/627 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs143393335, COSV60921289; called by muse, mutect2, varscan2
- NYAP2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 269/560 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs375169851; called by muse, mutect2, varscan2
- PCDHA4 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 322/784 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs782686583, COSV63545719; called by muse, mutect2, varscan2
- PHOX2A | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 351/786 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV53356772; called by muse, mutect2, varscan2
- ZNF668 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 145/322 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs767695513; called by muse, mutect2, varscan2
- ADAM10 | c.736-2A>C p.X246_splice | Splice Site (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- DSPP | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 319/763 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FGFR1OP2 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 162/349 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- FRMD8 | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 222/503 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- KRT23 | c.380C>A p.T127K | Missense Mutation (SNP) | VAF 202/455 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NFIX | c.468C>G p.C156W | Missense Mutation (SNP) | VAF 240/537 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN12 | c.1706C>T p.T569I | Missense Mutation (SNP) | VAF 185/535 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.094); called by muse, mutect2
- ADM5 | c.318T>C p.A106= | Silent (SNP) | VAF 124/302 reads (41%) | called by muse, mutect2, varscan2
- AMER3 | c.624G>T p.P208= | Silent (SNP) | VAF 166/382 reads (43%) | called by muse, mutect2, varscan2
- DNAH17 | c.8124C>A p.V2708= | Silent (SNP) | VAF 375/800 reads (47%) | called by muse, mutect2, varscan2
- GPR55 | c.318C>T p.Y106= | Silent (SNP) | VAF 304/530 reads (57%) | catalogued as rs139163265, COSV67407754; called by muse, mutect2, varscan2
- PDXDC1 | c.2217G>A p.P739= | Silent (SNP) | VAF 236/524 reads (45%) | catalogued as rs147386815; called by muse, mutect2, varscan2
- ZSCAN18 | c.1500G>A p.E500= | Silent (SNP) | VAF 176/398 reads (44%) | catalogued as rs1163901211; called by muse, mutect2, varscan2
- BCLAF1 | c.2043+26dup | Intron (INS) | VAF 84/213 reads (39%) | catalogued as rs758993874; called by mutect2, varscan2
- HNRNPU | c.634+27G>T | Intron (SNP) | VAF 243/758 reads (32%) | called by muse, mutect2, varscan2
- LEPR | c.2673+53G>A | Intron (SNP) | VAF 115/241 reads (48%) | catalogued as rs533324063, COSV60759206; called by muse, mutect2, varscan2
- NISCH | c.1528+511C>A | Intron (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- PDE2A | c.704-67C>T | Intron (SNP) | VAF 75/178 reads (42%) | catalogued as rs1259129084; called by muse, mutect2, varscan2
- ST3GAL6 | c.-11-5054G>A | Intron (SNP) | VAF 132/349 reads (38%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.438+13dup | Intron (INS) | VAF 146/308 reads (47%) | catalogued as rs766986488; called by mutect2, varscan2
